Somatic mutation profile of tumor specimen 0DGOAU from CCDI case PBBTLT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.6 years (2,062 days).
Specimen 0DGOAU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04e9d2d0-c363-410e-8447-94ff36d90eb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGOB6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8a6d5fd-d66d-49b4-8f58-d17acc946946

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R5B | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 188/960 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs773858189; called by muse, mutect2, varscan2
- KDM7A | c.2648G>T p.G883V | Missense Mutation (SNP) | VAF 261/1144 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
